Somatic mutation profile of tumor specimen TCGA-S7-A7WL-01A (aliquot TCGA-S7-A7WL-01A-11D-A35I-08) from TCGA case TCGA-S7-A7WL, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 59.3 years (21,643 days).
Specimen TCGA-S7-A7WL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 641f7ccb-dcae-40ec-98e5-3df6240e979d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WL-10A (Blood Derived Normal), aliquot TCGA-S7-A7WL-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b72efbf-fb7a-446c-9877-aaae339b0f9d

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST5 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60341280; called by muse, mutect2, varscan2
- PGLYRP4 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.923); catalogued as rs1027033500; called by muse, mutect2
- ZNF510 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs143262029; called by muse, mutect2, varscan2
- ATF1 | c.715A>C p.K239Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GREB1 | c.3314G>C p.G1105A | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, varscan2
- MECP2 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- NF1 | c.1284_1296del p.K428Nfs*41 | Frame Shift Del (DEL) | VAF 22/33 reads (67%) | called by mutect2, pindel, varscan2
- PLCB3 | c.3363_3370del p.T1122* | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- REM2 | c.502del p.Y168Mfs*84 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- ACAT2 | c.144T>G p.A48= | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- EPO | c.495C>T p.F165= | Silent (SNP) | VAF 87/132 reads (66%) | catalogued as rs1456636405; called by muse, mutect2, varscan2
- MAP1A | c.6792C>T p.T2264= | Silent (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
